Somatic mutation profile of tumor specimen TCGA-D7-8578-01A (aliquot TCGA-D7-8578-01A-21D-2340-08) from TCGA case TCGA-D7-8578, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.9 years (26,620 days).
Specimen TCGA-D7-8578-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b249bae2-b5f5-4fdc-89b0-8434c59b2af5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-8578-10A (Blood Derived Normal), aliquot TCGA-D7-8578-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0c059ef-ce13-42bd-9602-89c77e94ce64

The open-access MAF lists 57 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 40, Silent 12, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC011462.1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs753231061, COSV54195463; called by muse, mutect2, varscan2
- ADCY2 | c.2149A>G p.T717A | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs768691352, COSV57858767; called by muse, mutect2, varscan2
- ADCY3 | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333561857, COSV53164277; called by muse, mutect2, varscan2
- ADGRG5 | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs754466984, COSV61082576; called by muse, mutect2, varscan2
- ASB4 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1172134558, COSV57942843; called by muse, mutect2
- ATN1 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.986); catalogued as rs781823465, COSV63110218; called by muse, mutect2, varscan2
- B4GALT5 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65492639; called by muse, mutect2, varscan2
- BCL10 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as rs147850504; called by muse, mutect2, varscan2
- BROX | c.190T>C p.Y64H | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61798893; called by muse, mutect2, varscan2
- C16orf71 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs1336812617, COSV54786992; called by muse, mutect2, varscan2
- CAPN13 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 63/543 reads (12%) | catalogued as rs1438891666, COSV54428341; called by muse, mutect2, varscan2
- CCN4 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as rs760709240, COSV51529438, COSV99137085; called by muse, mutect2
- CELSR2 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs762541244, COSV54766692; called by muse, mutect2, varscan2
- CELSR3 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50839846; called by muse, mutect2, varscan2
- CENPB | c.1115G>C p.W372S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60144288; called by muse, mutect2, varscan2
- CTSS | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100934979; called by muse, mutect2, varscan2
- DPF3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs199891961, COSV63498651; called by muse, mutect2, varscan2
- EDIL3 | c.234C>A p.C78* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99677747; called by muse, mutect2, varscan2
- EHMT2 | c.3434G>A p.R1145Q | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs760598540, COSV57665749; called by muse, mutect2, varscan2
- FAM120C | c.2851A>G p.I951V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.733); catalogued as rs1557121282, COSV60257409; called by muse, mutect2, varscan2
- FAT2 | c.8834A>T p.Y2945F | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV55813084; called by muse, mutect2, varscan2
- FAT3 | c.12908G>A p.R4303Q | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.67); catalogued as COSV53074859; called by muse, mutect2, varscan2
- FBXO4 | c.766A>C p.N256H | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55851207; called by muse, mutect2, varscan2
- GEMIN4 | c.1979T>G p.L660W | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56744846; called by muse, mutect2
- GUCA1A | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs778379606, COSV50003450, COSV50003885; called by muse, mutect2, varscan2
- HMCN1 | c.5584A>C p.K1862Q | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV54876472; called by muse, mutect2, varscan2
- IFI44L | c.953G>A p.C318Y | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374146000, COSV60726626; called by muse, mutect2, varscan2
- IGFN1 | c.3413G>A p.R1138H (on ENST00000295591 / NM_001367841.1; = p.R3595H on NM_001164586.2) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs776150445, COSV55165711; called by muse, mutect2
- LEF1 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as rs978384163, COSV54463251; called by muse, mutect2, varscan2
- MUC6 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs547156930, COSV70133356; called by muse, mutect2, varscan2
- NAP1L2 | c.815T>A p.I272N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV65172157; called by muse, mutect2, varscan2
- NLRP2 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.693); catalogued as rs767901107, COSV54752314, COSV99672463; called by muse, mutect2, varscan2
- NRDE2 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765110421, COSV62962108; called by muse, mutect2, varscan2
- PJA2 | c.1505G>T p.W502L | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63271643; called by muse, mutect2, varscan2
- PREX1 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 69/577 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64247761; called by muse, mutect2, varscan2
- RALBP1 | c.1949G>A p.R650K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs749079878, COSV50034270; called by muse, mutect2, varscan2
- SLC13A2 | c.800T>A p.F267Y | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58992504; called by muse, mutect2, varscan2
- SLC4A4 | c.1053+1G>T p.X351_splice (on ENST00000264485 / NM_001098484.3; = p.X307_splice on NM_003759.4) | Splice Site (SNP) | VAF 11/38 reads (29%) | catalogued as COSV52614691, COSV52638447; called by muse, mutect2, varscan2
- SYDE1 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 109/472 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs921954725, COSV54617866; called by muse, mutect2, varscan2
- TENM3 | c.4396G>A p.A1466T | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs371087410, COSV69299200; called by muse, mutect2, varscan2
- TRPM3 | c.2230G>A p.V744M (on ENST00000357533 / NM_001366142.2; = p.V587M on NM_020952.6) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs747713615, COSV62579795; called by muse, mutect2, varscan2
- YWHAE | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.072); catalogued as COSV51980464; called by muse, mutect2, varscan2
- PRDM13 | c.35dup p.S13Efs*34 | Frame Shift Ins (INS) | VAF 7/64 reads (11%) | called by mutect2, pindel, varscan2
- RBBP6 | c.4810dup p.T1604Nfs*5 | Frame Shift Ins (INS) | VAF 25/203 reads (12%) | called by mutect2, pindel, varscan2
- CDK13 | c.4320C>T p.S1440= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV51696340; called by muse, mutect2, varscan2
- ENDOD1 | c.309C>T p.D103= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV53588546; called by muse, mutect2, varscan2
- FCHSD2 | c.589C>A p.R197= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as rs758252874, COSV60806577; called by muse, mutect2, varscan2
- HIPK1 | c.276G>T p.S92= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as COSV65783075; called by muse, mutect2, varscan2
- KCNT2 | c.723T>A p.S241= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV54063880; called by muse, mutect2, varscan2
- NLRC5 | c.618C>T p.D206= | Silent (SNP) | VAF 56/326 reads (17%) | catalogued as rs752886380, COSV52648943; called by muse, mutect2, varscan2
- PML | c.1647C>T p.A549= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs748216241, COSV51441998; called by muse, mutect2
- PTCHD3 | c.186G>A p.S62= | Silent (SNP) | VAF 23/164 reads (14%) | catalogued as rs1392843137, COSV71256281; called by muse, mutect2, varscan2
- SOWAHB | c.513G>A p.P171= | Silent (SNP) | VAF 2/10 reads (20%) | called by muse, mutect2
- ST8SIA5 | c.924G>A p.A308= | Silent (SNP) | VAF 39/169 reads (23%) | catalogued as COSV59329882, COSV59330576; called by muse, mutect2, varscan2
- UFD1 | c.645C>T p.D215= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as rs374934335; called by muse, mutect2, varscan2
- ZNF76 | c.966C>T p.C322= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs377680153, COSV57590829; called by muse, mutect2, varscan2
